Gene-level copy-number profile of tumor specimen C3L-01637-02 (profiled together with C3L-01637-03) from CPTAC case C3L-01637, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 78.6 years (28,706 days).
Specimen C3L-01637-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4a025eaa-f0a7-4994-bfa1-772c0250affb.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-01637-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,217 have no estimate.
https://portal.gdc.cancer.gov/files/26c6cbb9-7bfc-4deb-a357-7e17e7382fa6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 23; copy number 2: 57,996; copy number 3: 308; copy number 4: 31; copy number 6: 43; copy number 8: 5.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 48 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr18:31,058,840–32,773,023, 48 genes, copy number 6–8 (within-gene range 3–8): DSC2, DSCAS, DSC1, AC012417.1, DSG1, DSG1-AS1, RNU6-167P, DSG4, Y_RNA, DSG3, AC021549.1, DSG2, DSG2-AS1, TTR, B4GALT6, AC017100.1, RN7SKP44, LRRC37A7P, AC017100.2, SLC25A52, TRAPPC8, AC022960.1, AC022960.3, AC022960.2, RNU6-1050P, AC009831.1, PGDP1, AC009831.2, AC009831.4, RNF125, AC011825.3, AC009831.3, AC011825.1, AC011825.4, RNF138, AC011825.2, GAREM1, RNA5SP453, MEP1B, CLUHP6, AC015563.1, Y_RNA, AC015563.2, HNRNPA1P7, AC025887.2, WBP11P1, AC025887.1, KLHL14.

Autosomal genes at a single copy (total copy number 1): 23. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
